Somatic mutation profile of tumor specimen TCGA-AL-3472-01A (aliquot TCGA-AL-3472-01A-01D-1252-08) from TCGA case TCGA-AL-3472, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 57.9 years (21,166 days).
Specimen TCGA-AL-3472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 224df25c-581b-40d5-8bb9-c52ab43c7581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-3472-10A (Blood Derived Normal), aliquot TCGA-AL-3472-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d08d9fc-9ac9-4866-bfc2-8a1783b0143c

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Splice Site 4, Frame Shift Ins 3, Frame Shift Del 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3209T>A p.V1070E | Missense Mutation (SNP) | VAF 158/266 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59257121, COSV59259138, COSV59261515; called by muse, varscan2
- AHI1 | c.2906C>G p.T969S | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs760411761, COSV55627235; called by muse, mutect2, varscan2
- CLEC16A | c.665A>C p.N222T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV68499382; called by muse, mutect2, varscan2
- CRTC2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV57842648; called by muse, mutect2, varscan2
- FGF6 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57403895; called by muse, mutect2, varscan2
- FGF6 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV57403905; called by muse, mutect2, varscan2
- GGN | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV53056887; called by muse, mutect2, varscan2
- GRIK3 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV66139322, COSV66145636; called by muse, mutect2, varscan2
- INPP5J | c.1799G>C p.W600S (on ENST00000331075 / NM_001284285.2; = p.W232S on NM_001002837.2) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58512813; called by muse, mutect2, varscan2
- INTU | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56539633; called by muse, mutect2, varscan2
- ITIH3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV56254758; called by muse, mutect2, varscan2
- KIAA0513 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs148950418; called by muse, mutect2, varscan2
- KLHL9 | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV62921541; called by muse, mutect2, varscan2
- LAG3 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV52567373; called by muse, mutect2, varscan2
- LRRK1 | c.3622C>A p.H1208N | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52610238; called by muse, mutect2, varscan2
- LYAR | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as rs778654068, COSV58642730; called by muse, mutect2, varscan2
- MPRIP | c.2959+1G>A p.X987_splice | Splice Site (SNP) | VAF 70/239 reads (29%) | catalogued as COSV57926926; called by muse, mutect2, varscan2
- MUC16 | c.24118A>G p.T8040A | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV67463351, COSV67477778; called by muse, mutect2, varscan2
- NAV2 | c.1676C>T p.S559F (on ENST00000396087 / NM_001244963.2; = p.S536F on NM_145117.5) | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV62316341; called by muse, mutect2, varscan2
- NDUFS7 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as rs1368390410, COSV52039165; called by muse, mutect2, varscan2
- NLRP8 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as COSV52586776; called by muse, mutect2, varscan2
- OR10G8 | c.619T>G p.S207A | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.411); catalogued as COSV70908512, COSV70908735; called by muse, mutect2, varscan2
- PKHD1 | c.7952T>C p.L2651P | Missense Mutation (SNP) | VAF 65/72 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61873900; called by muse, mutect2, varscan2
- PRR12 | c.1541C>T p.P514L (on ENST00000615927; = p.P1335L on NM_020719.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV69817564; called by muse, mutect2, varscan2
- RBM19 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as rs1487627647, COSV55691506; called by muse, mutect2, varscan2
- SF3B1 | c.3505G>A p.V1169I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.385); catalogued as COSV59213252; called by muse, mutect2, varscan2
- SLC22A23 | c.863T>A p.F288Y | Missense Mutation (SNP) | VAF 57/58 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66673356; called by muse, mutect2, varscan2
- SLC25A12 | c.1585G>C p.G529R | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55533258; called by muse, mutect2, varscan2
- SLC25A2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 196/478 reads (41%) | catalogued as rs782351910, COSV53403691; called by muse, mutect2, varscan2
- ST14 | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs1318712889, COSV53833083; called by muse, mutect2, varscan2
- TSGA10 | c.938+2T>G p.X313_splice | Splice Site (SNP) | VAF 98/198 reads (49%) | catalogued as COSV61823168; called by muse, mutect2, varscan2
- ULK1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58856348; called by muse, mutect2, varscan2
- USH2A | c.7553G>A p.S2518N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as COSV56364631, COSV56403711; called by muse, mutect2, varscan2
- ZNF423 | c.2220G>C p.K740N (on ENST00000563137 / NM_001379286.1; = p.K732N on NM_015069.4) | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52187077; called by muse, mutect2, varscan2
- ZNF583 | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52402267; called by muse, mutect2, varscan2
- ZNF654 | c.3268A>T p.R1090* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58805749; called by muse, mutect2, varscan2
- EEF2 | c.219-4_219-2del p.X73_splice | Splice Site (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.4598del p.N1533Tfs*17 | Frame Shift Del (DEL) | VAF 50/149 reads (34%) | called by mutect2, pindel, varscan2
- NEDD4 | c.267dup p.E90* | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- PER2 | c.825-11_829del p.X275_splice | Splice Site (DEL) | VAF 49/143 reads (34%) | called by mutect2, pindel, varscan2
- PSAT1 | c.890dup p.N297Kfs*2 | Frame Shift Ins (INS) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- SRRM2 | c.4280dup p.M1427Ifs*22 | Frame Shift Ins (INS) | VAF 143/397 reads (36%) | called by mutect2, pindel, varscan2
- TRIM15 | c.1371del p.G458Vfs*6 | Frame Shift Del (DEL) | VAF 71/185 reads (38%) | called by mutect2, pindel, varscan2
- HAPLN2 | c.342C>T p.V114= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV54815669; called by muse, mutect2, varscan2
- MEI1 | c.3564C>A p.L1188= | Silent (SNP) | VAF 71/185 reads (38%) | catalogued as COSV55902771; called by muse, mutect2, varscan2
- MROH5 | c.2067C>T p.D689= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs372465445; called by muse, mutect2, varscan2
- MYH13 | c.807G>C p.L269= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52827640; called by muse, mutect2, varscan2
- PFKL | c.1572C>T p.I524= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV62463373; called by muse, varscan2
- PLTP | c.693C>T p.D231= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV62464580; called by muse, mutect2, varscan2
- PSD2 | c.840T>C p.D280= | Silent (SNP) | VAF 253/545 reads (46%) | catalogued as COSV51199367; called by muse, mutect2, varscan2
- RPL12 | c.15C>T p.F5= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as rs768761191, COSV55938358; called by muse, mutect2, varscan2
- SLC12A5 | c.1131C>T p.I377= (on ENST00000454036 / NM_001134771.2; = p.I354= on NM_020708.5) | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV54793029; called by muse, mutect2, varscan2
- TMTC1 | c.2161T>C p.L721= (on ENST00000539277 / NM_001193451.2; = p.L613= on NM_175861.3) | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV55480551; called by muse, mutect2, varscan2
- ACYP1 | c.84+1759C>G | Intron (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99465312; called by muse, mutect2, varscan2
